Somatic mutation profile of tumor specimen 0DVJOV from CCDI case PBCMTA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,569 days).
Specimen 0DVJOV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 686d8bf1-d442-43cf-9f6f-55c97ccb155f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7cb3050-cafe-479d-a93e-a91b7a4e3d9b

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXPH5 | c.3437G>A p.G1146D | Missense Mutation (SNP) | VAF 71/410 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1243526472; called by muse, mutect2, varscan2
- LAMA2 | c.8356C>T p.R2786C | Missense Mutation (SNP) | VAF 143/405 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs199806512, COSV70344186; called by muse, mutect2, varscan2
- MPO | c.1881G>A p.A627= | Silent (SNP) | VAF 145/403 reads (36%) | catalogued as rs780457377; called by muse, mutect2, varscan2
